Somatic mutation profile of tumor specimen TCGA-ZJ-AAXJ-01A (aliquot TCGA-ZJ-AAXJ-01A-11D-A42O-09) from TCGA case TCGA-ZJ-AAXJ, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, keratinizing, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IIB; Age at diagnosis: 43.8 years (16,007 days).
Specimen TCGA-ZJ-AAXJ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 108110d4-a79a-46a1-9070-27a1bc10fba3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-ZJ-AAXJ-10A (Blood Derived Normal), aliquot TCGA-ZJ-AAXJ-10A-01D-A42R-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/21ab6964-d008-4553-9099-7940eb698261

The open-access MAF lists 108 somatic variants for this specimen: 76 protein-altering or splice-affecting, 32 silent.
By variant classification: Missense Mutation 56, Silent 32, Nonsense Mutation 12, Frame Shift Del 3, Frame Shift Ins 2, In Frame Ins 1, In Frame Del 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCA12 | c.7277G>A p.R2426Q (on ENST00000272895 / NM_173076.3; = p.R2108Q on NM_015657.3) | Missense Mutation (SNP) | VAF 18/31 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as rs761068277, COSV55975031; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ACVRL1 | c.1142T>C p.L381P | Missense Mutation (SNP) | VAF 24/52 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1085307417, CM083473, COSV101187796; ClinVar: pathogenic; called by muse, mutect2, varscan2
- NFE2L2 | c.235G>C p.E79Q | Missense Mutation (SNP) | VAF 34/84 reads (40%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1057519922, COSV67959999, COSV67960008, COSV67960140; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ABCC4 | c.1085G>A p.R362Q | Missense Mutation (SNP) | VAF 13/50 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.477); catalogued as rs986813068, COSV100972293; called by muse, mutect2, varscan2
- ADAM21 | c.1786C>T p.H596Y | Missense Mutation (SNP) | VAF 35/98 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.869); catalogued as COSV99960627; called by muse, mutect2, varscan2
- ANKRD20A2P | c.163C>T p.R55C | Missense Mutation (SNP) | VAF 59/479 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.007); catalogued as COSV101111773; called by muse, mutect2, varscan2
- APEX1 | c.20A>G p.K7R | Missense Mutation (SNP) | VAF 4/78 reads (5%) | SIFT tolerated (0.26); PolyPhen benign (0.337); catalogued as COSV51657232, COSV51658489; called by muse, mutect2
- APPL1 | c.1048A>G p.K350E | Missense Mutation (SNP) | VAF 22/47 reads (47%) | SIFT deleterious (0); PolyPhen benign (0.027); catalogued as COSV99897451; called by muse, mutect2, varscan2
- C6orf118 | c.1375C>T p.Q459* | Nonsense Mutation (SNP) | VAF 16/67 reads (24%) | catalogued as COSV100024217; called by muse, mutect2, varscan2
- CACNA1A | c.3799G>A p.E1267K | Missense Mutation (SNP) | VAF 30/91 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1555751762, COSV100801345; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CACNA1E | c.6737A>T p.E2246V (on ENST00000367573 / NM_001205293.3; = p.E2203V on NM_000721.4) | Missense Mutation (SNP) | VAF 11/52 reads (21%) | SIFT tolerated (0.05); PolyPhen benign (0.038); catalogued as COSV100701403; called by muse, mutect2, varscan2
- CDKL3 | c.1186C>T p.P396S | Missense Mutation (SNP) | VAF 31/95 reads (33%) | SIFT tolerated (0.74); PolyPhen benign (0); catalogued as rs1225873423, COSV99527666; called by muse, mutect2, varscan2
- CECR2 | c.1171C>T p.R391* (on ENST00000342247 / NM_001290047.2; = p.R208* on NM_001290046.1) | Nonsense Mutation (SNP) | VAF 26/45 reads (58%) | catalogued as COSV52843439; called by muse, mutect2, varscan2
- CELA3B | c.486G>A p.W162* | Nonsense Mutation (SNP) | VAF 22/56 reads (39%) | catalogued as rs543692001, COSV61404657, COSV99055974; called by muse, mutect2, varscan2
- CERK | c.163T>C p.S55P | Missense Mutation (SNP) | VAF 13/25 reads (52%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.68); catalogued as rs1473921550, COSV99348450; called by muse, mutect2, varscan2
- CHUK | c.2131G>C p.E711Q | Missense Mutation (SNP) | VAF 30/92 reads (33%) | SIFT tolerated (0.29); PolyPhen benign (0.026); catalogued as COSV100957009; called by muse, mutect2, varscan2
- COPB1 | c.385G>A p.E129K | Missense Mutation (SNP) | VAF 23/64 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV99999308; called by muse, mutect2, varscan2
- CS | c.1318C>T p.R440* | Nonsense Mutation (SNP) | VAF 62/121 reads (51%) | catalogued as rs1341190437, COSV100369919; called by muse, mutect2, varscan2
- DNAJB7 | c.787G>A p.V263M | Missense Mutation (SNP) | VAF 21/71 reads (30%) | SIFT tolerated (0.34); PolyPhen benign (0.022); catalogued as rs751714280, COSV53422054; called by muse, mutect2, varscan2
- DNMT3A | c.1771A>G p.T591A | Missense Mutation (SNP) | VAF 38/108 reads (35%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as rs779611021, COSV99260053; called by muse, mutect2, varscan2
- DQX1 | c.922G>A p.V308I | Missense Mutation (SNP) | VAF 38/86 reads (44%) | SIFT tolerated (0.65); PolyPhen benign (0); catalogued as rs540562599, COSV101098804, COSV66353160; called by muse, mutect2, varscan2
- EDA | c.397A>G p.M133V | Missense Mutation (SNP) | VAF 26/103 reads (25%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0); catalogued as COSV100999467; called by muse, mutect2, varscan2
- EDEM3 | c.2561A>G p.N854S | Missense Mutation (SNP) | VAF 25/99 reads (25%) | SIFT tolerated, low confidence (0.74); PolyPhen benign (0); catalogued as COSV100544974; called by muse, mutect2, varscan2
- ERICH5 | c.491C>T p.A164V | Missense Mutation (SNP) | VAF 3/29 reads (10%) | SIFT tolerated (0.2); PolyPhen benign (0.147); catalogued as COSV100582683; called by muse, mutect2
- FREM2 | c.799C>A p.R267S | Missense Mutation (SNP) | VAF 21/68 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.313); catalogued as COSV99747242; called by muse, mutect2, varscan2
- FSIP2 | c.20032G>C p.E6678Q | Missense Mutation (SNP) | VAF 33/89 reads (37%) | SIFT tolerated (0.63); PolyPhen benign (0.169); catalogued as COSV100554259; called by muse, mutect2, varscan2
- GGA3 | c.204G>T p.V68= | Splice Region (SNP) | VAF 44/50 reads (88%) | catalogued as COSV99821952; called by muse, mutect2, varscan2
- GOLGA1 | c.1147C>T p.Q383* | Nonsense Mutation (SNP) | VAF 10/35 reads (29%) | catalogued as COSV101001977, COSV65221499; called by muse, mutect2, varscan2
- GPT2 | c.901G>A p.V301M | Missense Mutation (SNP) | VAF 15/43 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100412815; called by muse, mutect2, varscan2
- HMX2 | c.493G>C p.E165Q | Missense Mutation (SNP) | VAF 17/25 reads (68%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs751457489, COSV100378686, COSV100378769, COSV60592747; called by muse, mutect2, varscan2
- HTATSF1 | c.365C>T p.S122L | Missense Mutation (SNP) | VAF 87/235 reads (37%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as COSV99511430; called by muse, mutect2, varscan2
- INSR | c.2152C>G p.Q718E | Missense Mutation (SNP) | VAF 14/68 reads (21%) | SIFT tolerated (0.66); PolyPhen benign (0); catalogued as COSV57158843; called by muse, mutect2, varscan2
- KANK4 | c.2164G>A p.E722K | Missense Mutation (SNP) | VAF 10/20 reads (50%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as COSV100443103; called by muse, mutect2, varscan2
- KCNN2 | c.1125C>A p.C375* (on ENST00000264773; = p.C587* on NM_021614.4) | Nonsense Mutation (SNP) | VAF 13/37 reads (35%) | catalogued as COSV99298929; called by muse, mutect2, varscan2
- KIF4A | c.2833G>C p.E945Q | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT tolerated (0.08); PolyPhen benign (0.265); catalogued as COSV100979419; called by muse, mutect2, varscan2
- LNX2 | c.1222C>T p.Q408* | Nonsense Mutation (SNP) | VAF 22/82 reads (27%) | catalogued as COSV100310519; called by muse, mutect2, varscan2
- MAP3K20 | c.407C>T p.S136L | Missense Mutation (SNP) | VAF 39/95 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100168797; called by muse, mutect2, varscan2
- MMP2 | c.1293C>A p.F431L | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT tolerated (0.14); PolyPhen benign (0.02); catalogued as COSV99527490; called by mutect2, varscan2
- MS4A6A | c.488C>A p.S163Y | Missense Mutation (SNP) | VAF 20/64 reads (31%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV100124572; called by muse, mutect2, varscan2
- MUC5B | c.10333C>T p.P3445S | Missense Mutation (SNP) | VAF 38/109 reads (35%) | SIFT tolerated (0.58); PolyPhen benign (0.011); catalogued as COSV101500072; called by muse, mutect2, varscan2
- MYH1 | c.5251G>T p.E1751* | Nonsense Mutation (SNP) | VAF 38/106 reads (36%) | catalogued as COSV99875097; called by muse, mutect2, varscan2
- NSD1 | c.4760G>A p.R1587H | Missense Mutation (SNP) | VAF 46/134 reads (34%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as rs1316313643, COSV61782909; called by muse, mutect2, varscan2
- OR52I2 | c.455G>A p.R152H | Missense Mutation (SNP) | VAF 14/37 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); catalogued as rs139136347; called by muse, mutect2, varscan2
- PDZD8 | c.1067G>A p.W356* | Nonsense Mutation (SNP) | VAF 21/36 reads (58%) | catalogued as COSV100559421; called by muse, mutect2, varscan2
- PHF8 | c.1234C>A p.L412M (on ENST00000357988 / NM_001184896.1; = p.L376M on NM_015107.3) | Missense Mutation (SNP) | VAF 9/80 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.721); catalogued as COSV57678050; called by muse, mutect2, varscan2
- PLAC1 | c.586G>C p.D196H | Missense Mutation (SNP) | VAF 23/67 reads (34%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.661); catalogued as rs1440057490, COSV100821485, COSV63655551; called by muse, mutect2, varscan2
- POF1B | c.1564G>C p.E522Q | Missense Mutation (SNP) | VAF 29/104 reads (28%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); catalogued as COSV99426145; called by muse, mutect2, varscan2
- POGLUT2 | c.453G>A p.M151I | Missense Mutation (SNP) | VAF 22/58 reads (38%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.57); catalogued as COSV101050766; called by muse, mutect2, varscan2
- POR | c.646G>A p.E216K | Missense Mutation (SNP) | VAF 41/124 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101203482; called by muse, mutect2, varscan2
- PRORP | c.526G>A p.D176N | Missense Mutation (SNP) | VAF 15/43 reads (35%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99154965; called by muse, mutect2, varscan2
- RHOB | c.370G>A p.D124N | Missense Mutation (SNP) | VAF 18/39 reads (46%) | SIFT deleterious (0.03); PolyPhen benign (0.255); catalogued as COSV99695157; called by muse, mutect2, varscan2
- RHOJ | c.214G>A p.G72R | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs371394112; called by muse, mutect2, varscan2
- RPGRIP1 | c.424C>T p.R142C | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.877); catalogued as rs1442705881, COSV99250572; called by muse, mutect2, varscan2
- RTTN | c.3577C>T p.R1193* | Nonsense Mutation (SNP) | VAF 27/77 reads (35%) | catalogued as rs1280580731, COSV99731316; called by muse, mutect2, varscan2
- SLC35D3 | c.169G>C p.E57Q | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.946); catalogued as COSV100090419; called by muse, varscan2
- SLC39A6 | c.353C>T p.S118L | Missense Mutation (SNP) | VAF 31/71 reads (44%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as COSV99309403; called by muse, mutect2, varscan2
- SMC5 | c.1547G>C p.S516T | Missense Mutation (SNP) | VAF 35/112 reads (31%) | SIFT tolerated (0.27); PolyPhen benign (0.082); catalogued as COSV100746988; called by muse, mutect2, varscan2
- SVEP1 | c.4141G>A p.E1381K | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.146); catalogued as COSV57042400; called by muse, mutect2, varscan2
- SYT16 | c.560C>T p.S187F | Missense Mutation (SNP) | VAF 21/67 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101413524; called by muse, mutect2, varscan2
- TNR | c.1651C>T p.R551W | Missense Mutation (SNP) | VAF 25/42 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs200243334, COSV54917465, COSV99687753; called by muse, mutect2, varscan2
- TRIM49 | c.1098T>A p.N366K | Missense Mutation (SNP) | VAF 18/204 reads (9%) | SIFT tolerated (0.79); PolyPhen benign (0.13); catalogued as COSV100315910; called by muse, mutect2
- URB2 | c.3631G>C p.A1211P | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.641); catalogued as rs1311873364, COSV99270724; called by muse, mutect2, varscan2
- USP44 | c.643C>T p.R215C | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs763782999, COSV99311632; called by muse, varscan2
- VARS2 | c.2722G>T p.E908* | Nonsense Mutation (SNP) | VAF 19/49 reads (39%) | catalogued as COSV100422712; called by muse, mutect2, varscan2
- WDR59 | c.2162G>A p.R721Q | Missense Mutation (SNP) | VAF 14/50 reads (28%) | SIFT tolerated (0.56); PolyPhen benign (0.001); catalogued as rs199576675; called by muse, mutect2, varscan2
- ZC3H15 | c.931G>C p.D311H | Missense Mutation (SNP) | VAF 34/84 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); catalogued as COSV100551994; called by muse, mutect2, varscan2
- ZC3H7A | c.707C>T p.S236L | Missense Mutation (SNP) | VAF 28/72 reads (39%) | SIFT deleterious (0.03); PolyPhen benign (0.001); catalogued as COSV100865472; called by muse, mutect2, varscan2
- ZNF311 | c.952C>T p.L318F | Missense Mutation (SNP) | VAF 11/45 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101014082, COSV65853497; called by muse, mutect2, varscan2
- ZNF407 | c.3304C>T p.Q1102* | Nonsense Mutation (SNP) | VAF 24/74 reads (32%) | catalogued as COSV99995033; called by muse, mutect2, varscan2
- BEST3 | c.1989_1990del p.E664Gfs*11 | Frame Shift Del (DEL) | VAF 17/149 reads (11%) | called by mutect2, pindel, varscan2
- FAM83H | c.2616_2618del p.S873del | In Frame Del (DEL) | VAF 40/160 reads (25%) | called by mutect2, pindel, varscan2
- PIK3CA | c.335_340dup p.I112_L113dup | In Frame Ins (INS) | VAF 29/60 reads (48%) | called by mutect2, varscan2
- ROBO1 | c.4809del p.S1604Qfs*19 | Frame Shift Del (DEL) | VAF 32/60 reads (53%) | called by mutect2, pindel, varscan2
- SEMA3A | c.9dup p.L4Vfs*3 | Frame Shift Ins (INS) | VAF 32/108 reads (30%) | called by mutect2, pindel, varscan2
- SLC15A1 | c.1563dup p.P522Sfs*21 | Frame Shift Ins (INS) | VAF 28/118 reads (24%) | called by mutect2, pindel, varscan2
- ZNF750 | c.613_616del p.Y205Pfs*160 | Frame Shift Del (DEL) | VAF 36/48 reads (75%) | called by mutect2, pindel, varscan2
- BRINP2 | c.594C>T p.A198= | Silent (SNP) | VAF 12/60 reads (20%) | catalogued as rs147437706, COSV100837885; called by muse, mutect2, varscan2
- BRINP3 | c.1167C>T p.I389= | Silent (SNP) | VAF 43/90 reads (48%) | catalogued as rs572813236, COSV66516971; called by muse, mutect2, varscan2
- CDH12 | c.2271C>T p.L757= | Silent (SNP) | VAF 20/152 reads (13%) | catalogued as COSV101201747; called by muse, mutect2, varscan2
- CSMD2 | c.5235G>A p.K1745= | Silent (SNP) | VAF 6/29 reads (21%) | catalogued as COSV99586897; called by muse, mutect2, varscan2
- EGR2 | c.156C>T p.N52= | Silent (SNP) | VAF 12/27 reads (44%) | catalogued as COSV99654005; called by muse, mutect2, varscan2
- EPS15L1 | c.531G>A p.G177= | Silent (SNP) | VAF 26/97 reads (27%) | catalogued as rs1324012155, COSV99932758; called by muse, mutect2, varscan2
- GALNS | c.813C>T p.L271= | Silent (SNP) | VAF 16/52 reads (31%) | catalogued as COSV99242930; called by muse, mutect2, varscan2
- H4C5 | c.198G>C p.V66= | Silent (SNP) | VAF 32/100 reads (32%) | catalogued as rs145407769, COSV63486077, COSV63486239; called by muse, mutect2, varscan2
- HEPH | c.471G>A p.P157= (on ENST00000343002; = p.P211= on NM_138737.5) | Silent (SNP) | VAF 8/32 reads (25%) | catalogued as rs771425432, COSV57967829, COSV57968004; called by muse, mutect2, varscan2
- INPP4B | c.549C>T p.V183= | Silent (SNP) | VAF 26/51 reads (51%) | catalogued as rs773102037, COSV99523286; called by muse, mutect2, varscan2
- KLHL4 | c.981A>G p.E327= | Silent (SNP) | VAF 59/143 reads (41%) | catalogued as COSV100909221, COSV64140687; called by muse, mutect2, varscan2
- LDLRAD4 | c.204C>T p.I68= | Silent (SNP) | VAF 16/35 reads (46%) | catalogued as COSV100762006; called by muse, mutect2, varscan2
- LRAT | c.279C>T p.S93= | Silent (SNP) | VAF 8/16 reads (50%) | catalogued as COSV100312033; called by muse, mutect2, varscan2
- MB21D2 | c.381G>T p.L127= | Silent (SNP) | VAF 9/45 reads (20%) | catalogued as COSV101165036; called by muse, mutect2, varscan2
- MMS22L | c.2373C>G p.V791= | Silent (SNP) | VAF 36/107 reads (34%) | catalogued as COSV99246224; called by muse, mutect2, varscan2
- NR6A1 | c.828C>T p.Y276= (on ENST00000487099 / NM_033334.4; = p.Y271= on NM_001489.5) | Silent (SNP) | VAF 9/25 reads (36%) | catalogued as rs903537566, COSV100748459; called by muse, mutect2, varscan2
- ORC4 | c.153G>A p.L51= | Silent (SNP) | VAF 17/120 reads (14%) | catalogued as COSV51577100, COSV99932009; called by muse, mutect2, varscan2
- PCDHA11 | c.108G>A p.S36= | Silent (SNP) | VAF 12/87 reads (14%) | catalogued as rs375218342, COSV100248252; called by muse, mutect2, varscan2
- PLSCR1 | c.264G>A p.A88= | Silent (SNP) | VAF 62/164 reads (38%) | catalogued as rs747622828, COSV61012204; called by muse, mutect2, varscan2
- POGZ | c.399G>A p.Q133= | Silent (SNP) | VAF 15/46 reads (33%) | catalogued as COSV99652443; called by muse, mutect2, varscan2
- POU6F2 | c.774G>A p.Q258= | Silent (SNP) | VAF 6/32 reads (19%) | catalogued as COSV101302510, COSV101302900; called by mutect2, varscan2
- PRAMEF2 | c.738G>A p.T246= | Silent (SNP) | VAF 40/114 reads (35%) | catalogued as rs557708954, COSV53574406; called by muse, mutect2
- SCAF1 | c.84G>A p.T28= | Silent (SNP) | VAF 12/28 reads (43%) | catalogued as rs752202548, COSV55868461; called by muse, mutect2, varscan2
- SELP | c.624C>T p.H208= | Silent (SNP) | VAF 25/56 reads (45%) | catalogued as rs781066002, COSV99739196; called by muse, mutect2, varscan2
- SIPA1L3 | c.405C>G p.S135= | Silent (SNP) | VAF 22/330 reads (7%) | catalogued as COSV99727574; called by muse, mutect2
- SLC35D3 | c.123G>C p.L41= | Silent (SNP) | VAF 11/34 reads (32%) | catalogued as COSV100090417; called by muse, varscan2
- ST6GAL2 | c.846C>T p.A282= | Silent (SNP) | VAF 10/19 reads (53%) | catalogued as rs746962331, COSV100867703; called by muse, mutect2, varscan2
- STMN4 | c.84G>A p.L28= | Silent (SNP) | VAF 8/21 reads (38%) | catalogued as COSV99740666; called by muse, mutect2, varscan2
- THSD7B | c.4792C>T p.L1598= (on ENST00000272643; = p.L1596= on NM_001316349.2) | Silent (SNP) | VAF 7/28 reads (25%) | catalogued as COSV99745663; called by muse, mutect2, varscan2
- USP11 | c.1488G>A p.L496= (on ENST00000218348; = p.L453= on NM_001371072.1) | Silent (SNP) | VAF 23/54 reads (43%) | catalogued as COSV99510729; called by muse, mutect2, varscan2
- USP26 | c.894C>G p.P298= | Silent (SNP) | VAF 50/173 reads (29%) | catalogued as COSV100896557; called by muse, mutect2, varscan2
- ZACN | c.111C>G p.L37= | Silent (SNP) | VAF 12/62 reads (19%) | catalogued as COSV100134907; called by muse, mutect2, varscan2
